Somatic mutation profile of tumor specimen TCGA-WB-A81W-01A (aliquot TCGA-WB-A81W-01A-11D-A35I-08) from TCGA case TCGA-WB-A81W, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 41.1 years (15,001 days).
Specimen TCGA-WB-A81W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ff118e6-4052-475e-b336-66788116a4d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81W-10A (Blood Derived Normal), aliquot TCGA-WB-A81W-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6a87fb7-102f-4f51-9be4-4c3327c3f8d9

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNB2 | c.1874G>A p.R625H (on ENST00000324631 / NM_201596.3; = p.R570H on NM_000724.4) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs772911828, COSV99993061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCSER1 | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757079649; called by muse, mutect2, varscan2
- KCNH5 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100527565; called by muse, mutect2
- ZNF491 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.289); catalogued as rs1028132162; called by muse, mutect2, varscan2
- COG7 | c.2185C>T p.P729S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.89); called by muse, mutect2
- CSTF1 | c.5A>T p.Y2F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2
- F12 | c.128C>A p.T43N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP15 | c.779A>G p.N260S (on ENST00000280377 / NM_001351159.2; = p.N231S on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZHX2 | c.2191T>G p.Y731D | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF823 | c.1004A>G p.K335R (on ENST00000341191 / NM_001297610.2; = p.K291R on NM_017507.2) | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKAP9 | c.8112T>C p.H2704= (on ENST00000359028; = p.H2680= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- FGFR4 | c.2100G>A p.S700= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs750894321, COSV99450710; called by muse, mutect2, varscan2
- PRDM16 | c.1209C>T p.Y403= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1165059665; called by muse, varscan2
- YBX2 | c.822G>A p.P274= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs774610299, COSV50302175; called by mutect2, varscan2
